Somatic mutation profile of tumor specimen TCGA-97-A4M5-01A (aliquot TCGA-97-A4M5-01A-11D-A24P-08) from TCGA case TCGA-97-A4M5, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 84.0 years (30,665 days).
Specimen TCGA-97-A4M5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80d84e51-81ac-4eee-b33f-9aec47ac3ab8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-97-A4M5-10A (Blood Derived Normal), aliquot TCGA-97-A4M5-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc56a73a-86b6-4289-9f1f-c4f86f3e9870

The open-access MAF lists 162 somatic variants for this specimen: 124 protein-altering or splice-affecting, 34 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 34, Nonsense Mutation 21, Splice Site 2, 3'UTR 1, Intron 1, RNA 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABHD13 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as COSV101024031; called by muse, mutect2, varscan2
- AC011455.2 | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.557); catalogued as COSV99671097; called by muse, mutect2, varscan2
- AGTPBP1 | c.3139G>A p.D1047N (on ENST00000357081 / NM_001330701.2; = p.D1007N on NM_015239.2) | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.524); catalogued as COSV100429212; called by muse, mutect2, varscan2
- ALLC | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99377441; called by muse, mutect2, varscan2
- AMBN | c.1130G>T p.S377I | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as COSV100534257; called by muse, mutect2
- AMPD1 | c.1579C>T p.Q527* | Nonsense Mutation (SNP) | VAF 24/176 reads (14%) | catalogued as COSV100814800, COSV62415251; called by muse, mutect2, varscan2
- ANKRD44 | c.1490C>G p.S497* | Nonsense Mutation (SNP) | VAF 28/236 reads (12%) | catalogued as COSV99983953; called by muse, mutect2, varscan2
- APOB | c.9343G>A p.V3115I | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs373369264; called by muse, mutect2, varscan2
- ARHGAP19 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.018); catalogued as COSV57394787; called by muse, mutect2, varscan2
- ARHGEF26 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100726376; called by muse, mutect2, varscan2
- ATF5 | c.475C>G p.L159V | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.628); catalogued as COSV61314055; called by muse, mutect2
- C19orf57 | c.691G>C p.G231R | Missense Mutation (SNP) | VAF 13/205 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100694620; called by muse, mutect2
- C1QTNF3 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV51469969; called by muse, mutect2
- CASKIN2 | c.1631C>T p.S544L | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as COSV100050080; called by muse, mutect2, varscan2
- CCDC33 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs765926271, COSV100350378, COSV100350504; called by muse, mutect2, varscan2
- CCDC6 | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99569092; called by muse, mutect2, varscan2
- CCNT1 | c.2056C>T p.P686S | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99980452; called by muse, varscan2
- CCNT1 | c.1877C>G p.S626* | Nonsense Mutation (SNP) | VAF 14/116 reads (12%) | catalogued as COSV99980455; called by muse, mutect2, varscan2
- CD244 | c.432G>T p.K144N (on ENST00000368033 / NM_001166663.2; = p.K139N on NM_016382.4) | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as rs574301343, COSV100458206; called by muse, mutect2
- CDCP2 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV100313302; called by muse, mutect2
- CHD7 | c.5308G>A p.D1770N | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs762824174, COSV101417975; called by muse, mutect2, varscan2
- CHD8 | c.991C>T p.Q331* (on ENST00000646647 / NM_001170629.2; = p.Q52* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as rs1555318290, COSV101303033; called by muse, mutect2, varscan2
- CLCA1 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV99321873; called by muse, mutect2, varscan2
- COL3A1 | c.3667G>T p.E1223* | Nonsense Mutation (SNP) | VAF 21/176 reads (12%) | catalogued as COSV100482402; called by muse, mutect2, varscan2
- CPLANE1 | c.9020G>A p.R3007K | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV99949534; called by muse, mutect2
- CRB1 | c.3811G>T p.G1271* | Nonsense Mutation (SNP) | VAF 11/157 reads (7%) | catalogued as COSV100957648; called by muse, mutect2
- CSNK2A1 | c.892T>G p.L298V | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.096); catalogued as COSV99424176; called by muse, mutect2
- CUBN | c.5879G>A p.W1960* | Nonsense Mutation (SNP) | VAF 7/68 reads (10%) | catalogued as rs915452419, COSV100912028, COSV100912960; called by muse, mutect2, varscan2
- DDX1 | c.1636C>G p.H546D | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99245815, COSV99246940; called by muse, mutect2, varscan2
- DIP2C | c.2875C>T p.Q959* | Nonsense Mutation (SNP) | VAF 14/109 reads (13%) | catalogued as COSV99789861; called by muse, mutect2, varscan2
- DLC1 | c.1321C>G p.Q441E | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV52299250, COSV99360856; called by muse, mutect2, varscan2
- DMAC2 | c.350A>T p.E117V | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.29); catalogued as COSV99700423; called by muse, mutect2
- DMAC2 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 22/252 reads (9%) | catalogued as COSV99700425; called by muse, mutect2
- DNAH10 | c.1189G>A p.D397N (on ENST00000409039; = p.D336N on NM_207437.3) | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.754); catalogued as rs760223312, COSV101291930; called by muse, mutect2
- DPP8 | c.1940A>G p.Y647C (on ENST00000341861 / NM_001320875.2; = p.Y631C on NM_017743.6) | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100202072; called by muse, mutect2, varscan2
- DPY19L1 | c.326C>G p.P109R | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100204432; called by muse, mutect2
- ENO2 | c.1111C>G p.H371D | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV99980145; called by muse, mutect2, varscan2
- FAN1 | c.2286C>G p.F762L | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs765013759, COSV100755799; called by muse, mutect2, varscan2
- FANCM | c.4683G>A p.M1561I | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99950396; called by muse, mutect2
- FH | c.721C>G p.P241A | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100844975; called by muse, mutect2
- FLT3 | c.2908C>A p.Q970K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1431460944, COSV99607274; called by muse, mutect2, varscan2
- FOXI1 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs773987289, COSV100089035; called by muse, mutect2, varscan2
- GABRB1 | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 11/110 reads (10%) | catalogued as rs77043713, COSV99780085; called by muse, mutect2, varscan2
- GDAP1L1 | c.548-1G>A p.X183_splice | Splice Site (SNP) | VAF 48/540 reads (9%) | catalogued as COSV100697452; called by muse, mutect2
- GIMAP7 | c.372G>A p.M124I | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.433); catalogued as COSV57958942; called by muse, mutect2, varscan2
- GRIN1 | c.1760G>A p.G587D | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100159778; called by muse, mutect2
- GRM5 | c.2471T>A p.I824N | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100550067; called by muse, mutect2
- HAUS6 | c.69C>G p.F23L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.192); catalogued as COSV100998077; called by muse, mutect2, varscan2
- HOMER1 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV99980555; called by muse, mutect2, varscan2
- HSPH1 | c.2326C>T p.Q776* | Nonsense Mutation (SNP) | VAF 61/403 reads (15%) | catalogued as COSV100184639; called by muse, mutect2, varscan2
- HTT | c.7810G>A p.E2604K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100750374; called by muse, mutect2
- HYDIN | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99861891; called by mutect2, varscan2
- IGF2BP1 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.154); catalogued as rs1024617698, COSV51736242; called by muse, mutect2, varscan2
- IPO8 | c.42C>G p.I14M | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.074); catalogued as COSV99804700; called by muse, varscan2
- KHDC3L | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.78); catalogued as rs1159857446, COSV64863683; called by muse, mutect2, varscan2
- LIN9 | c.586G>A p.E196K (on ENST00000366808 / NM_001270410.2; = p.E141K on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100066977, COSV60246545; called by muse, mutect2, varscan2
- LPCAT4 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1202232926, COSV100148817; called by muse, mutect2, varscan2
- LRRIQ1 | c.4720G>A p.D1574N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as rs911977371, COSV101279450; called by muse, mutect2, varscan2
- MAN2C1 | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.027); catalogued as rs759387214, COSV51247240; called by muse, mutect2, varscan2
- MAP1A | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100288037; called by muse, mutect2, varscan2
- MAP1A | c.1093G>C p.E365Q | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV100288038; called by muse, mutect2
- MASP2 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 32/297 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.213); catalogued as rs779641842, COSV53569337; called by muse, mutect2, varscan2
- MDGA2 | c.2485C>T p.Q829* (on ENST00000399232 / NM_001113498.2; = p.Q531* on NM_182830.4) | Nonsense Mutation (SNP) | VAF 11/104 reads (11%) | catalogued as rs765281786, COSV100636308, COSV62095044; called by muse, mutect2, varscan2
- MED23 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 15/130 reads (12%) | catalogued as COSV100644742; called by muse, mutect2, varscan2
- MMRN1 | c.3341C>G p.P1114R | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53343656, COSV99306375; called by muse, mutect2, varscan2
- MNDA | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 22/89 reads (25%) | catalogued as COSV100933235; called by muse, mutect2, varscan2
- MUC16 | c.16198C>T p.H5400Y | Missense Mutation (SNP) | VAF 43/623 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs747248575, COSV101198053, COSV67443181; called by muse, mutect2
- MYO1F | c.2004G>C p.Q668H | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100596331; called by muse, mutect2, varscan2
- MYOM2 | c.2594C>T p.T865M | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.238); catalogued as rs370494955, COSV100038325; called by muse, mutect2
- NBAS | c.5788G>A p.E1930K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.577); catalogued as COSV99866966; called by muse, mutect2
- NOL7 | c.299G>C p.R100P | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100702683; called by muse, mutect2
- NOLC1 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as rs760217848, COSV100893550; called by muse, mutect2
- NOSTRIN | c.1051G>A p.E351K (on ENST00000317647 / NM_001039724.4; = p.E273K on NM_052946.3) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100473117; called by muse, mutect2
- NSD1 | c.7531G>C p.D2511H | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); catalogued as rs575229932, COSV100728381, COSV100729780; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUP188 | c.2287C>G p.L763V | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.994); catalogued as COSV101001168; called by muse, mutect2, varscan2
- OLA1 | c.337C>T p.H113Y | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52973003, COSV99505789; called by muse, mutect2, varscan2
- OR1S1 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 10/123 reads (8%) | catalogued as COSV100515235; called by muse, mutect2
- OR2H1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs373932418, COSV101009771; called by muse, mutect2
- OR5A1 | c.553C>A p.P185T | Missense Mutation (SNP) | VAF 43/347 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV100118242, COSV57375662; called by muse, mutect2, varscan2
- OXSR1 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.407); catalogued as rs1436798799, COSV61257530; called by muse, mutect2, varscan2
- PAPPA2 | c.1276C>A p.L426M | Missense Mutation (SNP) | VAF 21/232 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100866520; called by muse, mutect2
- PCNX1 | c.2753C>T p.S918L | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); catalogued as COSV99453892; called by muse, mutect2
- PEAK1 | c.2912A>G p.H971R | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV100432382; called by muse, mutect2, varscan2
- PKDCC | c.1219A>T p.T407S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV99684637; called by muse, mutect2
- POGK | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as COSV63311414; called by muse, varscan2
- POMZP3 | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as COSV99300287; called by muse, mutect2, varscan2
- PPIL2 | c.408C>G p.I136M | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs1303838586, COSV100622422, COSV100622669; called by muse, mutect2, varscan2
- PRDM2 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as COSV52448644, COSV99340740; called by muse, mutect2, varscan2
- RAPGEF2 | c.3383-1G>T p.X1128_splice | Splice Site (SNP) | VAF 13/87 reads (15%) | catalogued as COSV100030475; called by muse, mutect2, varscan2
- RBBP7 | c.1061C>G p.S354* | Nonsense Mutation (SNP) | VAF 15/97 reads (15%) | catalogued as COSV100417812; called by muse, mutect2, varscan2
- RPGRIP1L | c.3841G>A p.D1281N | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as COSV50921252, COSV99030260; called by muse, mutect2, varscan2
- SBNO1 | c.3929C>T p.S1310L (on ENST00000420886; = p.S1309L on NM_018183.5) | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.966); catalogued as COSV99928669; called by muse, mutect2
- SEMG2 | c.1304C>G p.S435C | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.769); catalogued as COSV101033946, COSV65647353; called by muse, mutect2, varscan2
- SEMG2 | c.1702C>G p.H568D | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as COSV101033948; called by muse, mutect2, varscan2
- SERPINB4 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100345409; called by muse, mutect2, varscan2
- SIRT4 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as rs753915067, COSV52540710; called by muse, mutect2, varscan2
- SLC17A6 | c.1558C>T p.H520Y | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV54133405, COSV99580661; called by muse, mutect2
- SLC26A6 | c.1960G>C p.D654H | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV100258032; called by muse, mutect2, varscan2
- SLC6A3 | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1271645273, COSV99547801, COSV99548234; called by muse, mutect2, varscan2
- SLC7A14 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as rs530931888, COSV51582793, COSV51585816; called by muse, mutect2
- SMG1 | c.8151C>G p.I2717M | Missense Mutation (SNP) | VAF 27/266 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV101245097; called by muse, mutect2, varscan2
- SPZ1 | c.1274C>T p.S425L | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99698053; called by muse, mutect2
- STRN3 | c.1551G>C p.K517N (on ENST00000357479 / NM_001083893.2; = p.K433N on NM_014574.4) | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100670280; called by muse, mutect2, varscan2
- SUSD2 | c.1085C>T p.S362L | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV100844162; called by muse, mutect2
- TAPBPL | c.1281G>C p.Q427H | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs750591790, COSV99868925; called by muse, mutect2
- TAS2R7 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV53690111; called by muse, mutect2, varscan2
- TENT5B | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV100006459; called by muse, mutect2, varscan2
- TOP2A | c.3115G>C p.G1039R | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV101396024; called by muse, varscan2
- TPP2 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV101060160; called by muse, mutect2, varscan2
- TSC22D2 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100721179; called by muse, mutect2, varscan2
- USP29 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 16/173 reads (9%) | catalogued as COSV54146695, COSV99517615; called by muse, mutect2
- WDR7 | c.1549C>G p.Q517E | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV99588438; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2536C>G p.L846V | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99648199, COSV99649007; called by muse, mutect2, varscan2
- ZHX3 | c.699C>G p.I233M | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV100475426, COSV58387934; called by muse, mutect2, varscan2
- ZNF235 | c.1751C>G p.S584* | Nonsense Mutation (SNP) | VAF 17/165 reads (10%) | catalogued as COSV99349225; called by muse, mutect2, varscan2
- ZNF282 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100021388; called by muse, mutect2
- ZNF496 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.76); catalogued as COSV99665133; called by muse, mutect2, varscan2
- ZNF608 | c.2874G>A p.M958I | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV100100918; called by muse, mutect2
- ZNF776 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 7/178 reads (4%) | catalogued as COSV100414068; called by muse, mutect2
- ZNF831 | c.3211G>A p.D1071N | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV100925750; called by muse, mutect2, varscan2
- CMA1 | c.102del p.Y35Tfs*8 | Frame Shift Del (DEL) | VAF 30/255 reads (12%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.2259G>C p.Q753H | Missense Mutation (SNP) | VAF 5/111 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2
- TUBGCP5 | c.1897G>T p.E633* | Nonsense Mutation (SNP) | VAF 15/195 reads (8%) | called by muse, mutect2
- ADAMTS17 | c.684C>T p.L228= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs776936851, COSV99170356; called by muse, varscan2
- ADAMTS17 | c.678C>T p.I226= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV99170357; called by muse, varscan2
- ADCK1 | c.1365C>G p.L455= | Silent (SNP) | VAF 9/95 reads (9%) | catalogued as COSV99450862; called by muse, mutect2
- ANKAR | c.240C>T p.F80= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as rs1193294172, COSV55619344; called by muse, mutect2
- APOBR | c.1218G>A p.E406= (on ENST00000431282; = p.E415= on NM_018690.4) | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100112237; called by mutect2, varscan2
- DDN | c.1113G>C p.S371= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV100304859; called by muse, mutect2, varscan2
- DNAH7 | c.10287A>C p.P3429= | Silent (SNP) | VAF 24/165 reads (15%) | catalogued as COSV100413755; called by muse, mutect2, varscan2
- DOCK11 | c.2625C>G p.L875= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as COSV99352805; called by muse, mutect2, varscan2
- GBA2 | c.1953G>A p.V651= | Silent (SNP) | VAF 23/167 reads (14%) | catalogued as COSV100803283; called by muse, mutect2, varscan2
- GPC6 | c.546C>T p.F182= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as COSV65515974; called by muse, mutect2, varscan2
- GPR89B | c.1134C>G p.V378= | Silent (SNP) | VAF 40/528 reads (8%) | called by muse, mutect2
- HEPN1 | c.84C>G p.P28= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as COSV100005438, COSV100005862; called by muse, mutect2, varscan2
- IGHV3-73 | c.168C>T p.V56= | Silent (SNP) | VAF 16/162 reads (10%) | called by muse, mutect2, varscan2
- IL6 | c.510C>T p.T170= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV99331347; called by muse, mutect2
- KAT8 | c.582C>T p.F194= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as rs1214708550, COSV99571100; called by muse, mutect2
- LRSAM1 | c.12C>T p.F4= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as rs753536686, COSV100031115; called by muse, mutect2, varscan2
- MYH11 | c.1992G>A p.L664= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV100257632; called by muse, mutect2
- NLRP5 | c.2247C>T p.S749= | Silent (SNP) | VAF 22/316 reads (7%) | catalogued as rs149649207; ClinVar: likely benign; called by muse, mutect2
- NUP188 | c.2553C>G p.L851= | Silent (SNP) | VAF 58/578 reads (10%) | catalogued as COSV101001169; called by muse, mutect2, varscan2
- OSTC | c.55C>T p.L19= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as COSV100843157; called by muse, mutect2
- PCCA | c.1146C>T p.L382= | Silent (SNP) | VAF 29/184 reads (16%) | catalogued as COSV100886500; called by muse, mutect2, varscan2
- PCDHB2 | c.2040G>A p.P680= | Silent (SNP) | VAF 30/272 reads (11%) | catalogued as rs1352098597, COSV99164145, COSV99166862; called by muse, mutect2, varscan2
- PCDHGA5 | c.1002G>T p.V334= | Silent (SNP) | VAF 4/55 reads (7%) | catalogued as COSV99530090; called by muse, mutect2
- PPFIBP1 | c.1767C>T p.I589= (on ENST00000318304 / NM_177444.3; = p.I583= on NM_003622.4) | Silent (SNP) | VAF 23/201 reads (11%) | catalogued as COSV57291603; called by muse, mutect2, varscan2
- RAB5A | c.477C>T p.F159= | Silent (SNP) | VAF 29/204 reads (14%) | catalogued as COSV99810791; called by muse, mutect2, varscan2
- SEC24A | c.2580G>C p.L860= | Silent (SNP) | VAF 22/183 reads (12%) | catalogued as COSV101295014; called by muse, mutect2, varscan2
- SORBS2 | c.2799G>A p.P933= (on ENST00000284776 / NM_021069.5; = p.P499= on NM_003603.6) | Silent (SNP) | VAF 24/158 reads (15%) | catalogued as rs781675389, COSV99509425; called by muse, mutect2, varscan2
- TLN1 | c.3639G>C p.L1213= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV100147253; called by muse, mutect2, varscan2
- TMEM26 | c.162C>T p.L54= | Silent (SNP) | VAF 18/173 reads (10%) | catalogued as rs1368501812, COSV101051662, COSV104432566; called by muse, mutect2, varscan2
- TMEM38A | c.588C>G p.L196= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV99495102; called by muse, mutect2, varscan2
- TP53RK | c.600C>G p.L200= | Silent (SNP) | VAF 26/161 reads (16%) | catalogued as COSV100927738; called by muse, mutect2, varscan2
- TTI1 | c.1881A>C p.I627= | Silent (SNP) | VAF 25/239 reads (10%) | catalogued as COSV100989562; called by muse, mutect2, varscan2
- TTLL2 | c.87T>C p.I29= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV99514377; called by muse, mutect2, varscan2
- TUBGCP5 | c.2061G>T p.L687= | Silent (SNP) | VAF 31/282 reads (11%) | called by muse, mutect2, varscan2
- CTSL3P | n.334C>G | RNA (SNP) | VAF 10/113 reads (9%) | called by muse, mutect2
- PALM2AKAP2 | c.-93G>C | 5'UTR (SNP) | VAF 17/118 reads (14%) | catalogued as COSV99394679; called by muse, mutect2, varscan2
- STK36 | c.2587-191G>C | Intron (SNP) | VAF 16/131 reads (12%) | catalogued as COSV99830988; called by muse, mutect2, varscan2
- XIRP2 | c.*1029C>T | 3'UTR (SNP) | VAF 14/77 reads (18%) | catalogued as COSV99738135; called by muse, mutect2, varscan2
